MMRF case MMRF_1320 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/e59bd9ff-ffa1-4aa0-a18a-1c8dd9e9b39a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 63 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 63.3 years (23,123 days); ISS stage: II; Days to last known disease status: 1,475 days (4.0 years); Days to last follow up: 1,475 days (4.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 336 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 2 days; Days to treatment end: 336 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 337 days; Days to treatment end: 1,073 days (2.9 years).
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,139 days (3.1 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 4): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.74 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.503 mg/dL; Immunoglobulin G 4.58 g/L; Immunoglobulin A 34.9 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 4.89 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 6.7 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.68 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.1 mmol/L; Albumin 25 g/L; Total Protein 8 g/dL; Glucose 4.95 mmol/L.
- Day 129: M Protein 0.12 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.685 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.34 mg/dL; Immunoglobulin A 0.2 g/L; Beta 2 Microglobulin 1.86 µg/mL; Hemoglobin 7.38 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 0.703 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.13 mmol/L; Albumin 39 g/L; Total Protein 5.8 g/dL; Glucose 5.67 mmol/L.
- Day 173 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.383 mg/dL; Immunoglobulin G 7.37 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 8.18 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.56 ×10⁹/L; Platelets 173 ×10⁹/L; Creatinine 60.1 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 4.95 mmol/L.
- Day 234: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.56 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.35 mg/dL; Immunoglobulin G 7.51 g/L; Immunoglobulin A 0.07 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.4 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.61 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.84 mmol/L.
- Day 367 (ECOG 3): Serum Free Immunoglobulin Light Chain, Kappa 1.63 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.31 mg/dL; Immunoglobulin G 9.05 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.01 ×10⁹/L; Platelets 178 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.2 g/dL; Glucose 6.16 mmol/L.
- Day 451: M Protein 0.21 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.35 mg/dL; Immunoglobulin G 9.71 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.08 µg/mL; Hemoglobin 8.25 mmol/L; Leukocytes 3.8 ×10⁹/L; Absolute Neutrophil 2.13 ×10⁹/L; Platelets 205 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 6.11 mmol/L.
- Day 535: Serum Free Immunoglobulin Light Chain, Kappa 4.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.513 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.34 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 3.05 ×10⁹/L; Platelets 158 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 6.82 mmol/L.
- Day 647: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.944 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.61 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 8.06 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.87 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.6 g/dL; Glucose 6.33 mmol/L.
- Day 731: Serum Free Immunoglobulin Light Chain, Kappa 2.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.64 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 8.12 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 1.98 ×10⁹/L; Platelets 251 ×10⁹/L; Creatinine 62.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 40 g/L; Total Protein 6.5 g/dL; Glucose 5.01 mmol/L.
- Day 822: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.75 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.481 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.22 g/L; Immunoglobulin M 0.13 g/L; Beta 2 Microglobulin 2.1 µg/mL; Hemoglobin 8.43 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.35 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 44 g/L; Total Protein 6.8 g/dL; Glucose 6.33 mmol/L.
- Day 915 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.3 ×10⁹/L; Absolute Neutrophil 1.17 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 6.11 mmol/L.
- Day 990: M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.406 mg/dL; Immunoglobulin A 3.76 g/L; Hemoglobin 7.81 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.51 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL; Glucose 5.61 mmol/L.
- Day 1,073 (ECOG 2): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 9.95 g/L; Immunoglobulin A 4.56 g/L; Immunoglobulin M 0.13 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 0.827 ×10⁹/L; Platelets 130 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 1,144: M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.547 mg/dL; Immunoglobulin G 9.33 g/L; Immunoglobulin A 6.95 g/L; Immunoglobulin M 0.03 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.86 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 7.6 g/dL; Glucose 5.12 mmol/L.
- Day 1,286 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.78 mg/dL; Immunoglobulin G 4.7 g/L; Immunoglobulin A 1.73 g/L; Hemoglobin 6.39 mmol/L; Leukocytes 0.8 ×10⁹/L; Absolute Neutrophil 0.43 ×10⁹/L; Platelets 108 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.8 g/dL.
- Day 1,361 (ECOG 1): Hemoglobin 6.32 mmol/L; Leukocytes 2 ×10⁹/L; Absolute Neutrophil 1.19 ×10⁹/L; Platelets 124 ×10⁹/L.
- Day 1,475 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.217 mg/dL; Immunoglobulin A 0.77 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 3.2 ×10⁹/L; Absolute Neutrophil 2.15 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 10 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 6.49 mmol/L.

Other clinical attributes
- Day 1: Weight: 79 kg; Height: 180 cm.

Biospecimens (2 samples)
- Sample MMRF_1320_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1320_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
